Somatic mutation profile of tumor specimen TARGET-10-PAPFUF-09A (aliquot TARGET-10-PAPFUF-09A-01D) from TARGET case TARGET-10-PAPFUF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.5 years (2,747 days).
Specimen TARGET-10-PAPFUF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 460bae91-69fc-4407-b1ea-06a54b21c869.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFUF-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFUF-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bd4a8d1-f48d-4a6c-a2c5-8be35f003bd3

The open-access MAF lists 55 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 8, Intron 5, 5'UTR 2, 3'UTR 2, RNA 2, 3'Flank 2, 5'Flank 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1G | c.5144G>A p.R1715H | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755221106, CM1511857, COSV100662400; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ANK3 | c.12152C>T p.T4051M | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.23); catalogued as rs531332857, COSV55043015; called by muse, mutect2
- CCNY | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 21/189 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs764197479, COSV55188844; called by muse, mutect2, varscan2
- EFCAB12 | c.1093C>T p.R365W | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.319); catalogued as rs1263599299; called by muse, mutect2, varscan2
- FAM71A | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202026670, COSV99674804; called by muse, mutect2, varscan2
- HECTD2 | c.2326G>C p.E776Q | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.435); catalogued as COSV53222241; called by muse, mutect2
- HSP90B1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.015); catalogued as COSV55354202; called by muse, mutect2
- HTR6 | c.981C>G p.F327L | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53868970; called by muse, mutect2
- KIAA1210 | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.412); catalogued as COSV101273863; called by muse, mutect2
- LCT | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs758609978, COSV99930246; called by muse, mutect2, varscan2
- MUC16 | c.17701G>C p.E5901Q | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.349); catalogued as rs760021920; called by muse, mutect2
- MYH1 | c.2960C>T p.A987V | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as rs1184763135; called by muse, mutect2, varscan2
- NLRP4 | c.1232C>A p.T411K | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.796); catalogued as rs543755051, COSV56724704; called by muse, mutect2, varscan2
- RYR2 | c.9778C>T p.R3260W | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as rs765325906, COSV63658681; called by muse, mutect2, varscan2
- ZNF407 | c.5884G>A p.A1962T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs775567861; called by muse, mutect2, varscan2
- ALG14 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.443); called by muse, mutect2
- ARHGAP42 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- CCDC93 | c.858C>G p.I286M | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, mutect2
- DHX37 | c.2726_2727insAGA p.F909delinsLD | In Frame Ins (INS) | VAF 15/61 reads (25%) | called by mutect2, pindel, varscan2
- EIF2AK4 | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- EIF2B1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- FSIP2 | c.12794G>T p.G4265V | Missense Mutation (SNP) | VAF 20/181 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GON4L | c.3904C>G p.L1302V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HUWE1 | c.6227C>A p.A2076E | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IGHV3-43 | chr14:106470247 ACTTCCCCTCACTGTGTATCTTTTGCACAGTAATACAAGGCGGT>GTAAGG | Missense Mutation (DEL) | VAF 29/153 reads (19%) | called by pindel, varscan2*
- MTERF4 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NCAPH | c.1577C>G p.P526R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLRC4 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.377); called by muse, mutect2
- NLRP1 | c.1684C>G p.Q562E | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.449); called by muse, mutect2
- OR10D3 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); called by muse, mutect2
- OR1A1 | c.794A>G p.Y265C | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2
- PHYHIPL | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.173); called by muse, mutect2
- TENM4 | c.5771G>A p.W1924* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- GABRD | c.123C>T p.L41= | Silent (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- ICA1 | c.1116C>T p.D372= | Silent (SNP) | VAF 33/86 reads (38%) | called by muse, mutect2, varscan2
- IL18RAP | c.669C>T p.Y223= | Silent (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- MYO15B | c.8898C>T p.I2966= | Silent (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- MYO7B | c.2014C>T p.L672= | Silent (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- PCDHA12 | c.1233C>T p.S411= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs369536692; called by muse, mutect2, varscan2
- SATB2 | c.1005C>A p.I335= | Silent (SNP) | VAF 43/100 reads (43%) | catalogued as COSV53490188; called by muse, mutect2, varscan2
- ZNF469 | c.10077G>A p.A3359= (on ENST00000437464; = p.A3387= on NM_001367624.2) | Silent (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2
- AP000769.5 | chr11:65498707 C>G | 5'Flank (SNP) | VAF 13/184 reads (7%) | catalogued as rs1382418784; called by muse, mutect2
- ARL2BP | c.208-99G>A | Intron (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- C8orf74 | c.242-6521C>G | Intron (SNP) | VAF 32/82 reads (39%) | called by muse, mutect2, varscan2
- IFI27 | c.92-136G>A | Intron (SNP) | VAF 8/30 reads (27%) | catalogued as rs533471979; called by muse, mutect2
- IGHV1-45 | chr14:106506995 ins GGGGGGGAC | 3'Flank (INS) | VAF 39/126 reads (31%) | called by mutect2, pindel*, varscan2
- IGHV1-69D | chr14:106762091 ins TCTCCAGA | 3'Flank (INS) | VAF 5/59 reads (8%) | called by mutect2, pindel
- MIR4477B | n.39C>T | RNA (SNP) | VAF 6/34 reads (18%) | catalogued as rs751191207; called by muse, mutect2
- MUC15 | c.*1404A>C | 3'UTR (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- PLXNA3 | c.4287+38G>A | Intron (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- RECQL5 | c.2490-47G>T | Intron (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2, varscan2
- RPL5 | c.-61C>G | 5'UTR (SNP) | VAF 8/92 reads (9%) | catalogued as rs1402459095; called by muse, mutect2
- SMIM5 | c.-640C>T | 5'UTR (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2
- SSTR5-AS1 | n.730G>A | RNA (SNP) | VAF 8/18 reads (44%) | catalogued as rs1383146817; called by mutect2, varscan2
- TMBIM1 | c.*98C>G | 3'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
